Somatic mutation profile of tumor specimen 0DLRHQ from CCDI case PBBXZD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 11.9 years (4,356 days).
Specimen 0DLRHQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eeadbc6-a9fb-4f06-a434-46b5377c8b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d5ce094-8b00-40b3-9376-76f59405aeb4

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 229/956 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58615244, COSV58615703, COSV58615881; called by muse, varscan2
- CATSPERG | c.470-21G>T | Intron (SNP) | VAF 85/374 reads (23%) | called by muse, varscan2
